Somatic mutation profile of tumor specimen MP2PRT-PARLNT-TBP1-A (aliquot MP2PRT-PARLNT-TBP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARLNT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,295 days).
Specimen MP2PRT-PARLNT-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47a3f027-7698-43ad-9f06-1d695b3e5722.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARLNT-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARLNT-NM1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f67034a-328b-41a4-a673-dfe8bed7f0da

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 14/97 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, varscan2
- COL3A1 | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs759521597; called by muse, mutect2, varscan2
- GSPT2 | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 123/412 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61214657; called by muse, mutect2, varscan2
- LRIT1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 117/880 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs780183101, COSV100928157; called by muse, mutect2, varscan2
- MAGI1 | c.3473C>T p.A1158V (on ENST00000402939 / NM_001033057.2; = p.A1187V on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/336 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1210816472, COSV58315495; called by muse, mutect2, varscan2
- PKP2 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 174/426 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs759687672; called by muse, mutect2, varscan2
- PTPRM | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 135/448 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs531199027, COSV59857059; called by muse, mutect2, varscan2
- UNC13C | c.6367G>A p.G2123R | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs750345422, COSV52862254; called by muse, mutect2, varscan2
- CBL | c.1080T>A p.H360Q | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DHX9 | c.3736G>C p.G1246R | Missense Mutation (SNP) | VAF 197/644 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DOCK4 | c.2328G>C p.K776N | Missense Mutation (SNP) | VAF 179/361 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- PDE3A | c.1313C>G p.S438C | Missense Mutation (SNP) | VAF 164/422 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- FAM189A1 | c.735G>A p.P245= | Silent (SNP) | VAF 254/692 reads (37%) | catalogued as rs779517068; called by muse, mutect2, varscan2
- H1-5 | c.261C>G p.L87= | Silent (SNP) | VAF 422/692 reads (61%) | called by muse, mutect2, varscan2
- IGSF3 | c.3180G>A p.P1060= (on ENST00000369486 / NM_001007237.3; = p.P1080= on NM_001542.4) | Silent (SNP) | VAF 114/536 reads (21%) | catalogued as rs202172819, COSV100605038, COSV59590853; called by muse, mutect2, varscan2
- MMP2 | c.1221C>T p.H407= | Silent (SNP) | VAF 205/441 reads (46%) | catalogued as rs772843973, COSV54599130; called by muse, mutect2, varscan2
- NLRP7 | c.1230C>T p.G410= | Silent (SNP) | VAF 359/868 reads (41%) | catalogued as rs770690608; called by muse, mutect2, varscan2
- RORB | c.462C>T p.N154= (on ENST00000396204 / NM_001365023.1; = p.N143= on NM_006914.4) | Silent (SNP) | VAF 258/616 reads (42%) | catalogued as rs573233356, COSV65333322; called by muse, mutect2, varscan2
